TCGA case TCGA-D7-6519 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e37cae9e-0656-4b89-b326-739a5cc859e0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 64 years; Vital status: Alive.

Diagnoses (2)
1. Carcinoma, diffuse type (the primary disease): ICD-O-3 morphology code: 8145/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 64.1 years (23,413 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 625 days (1.7 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 16.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 237 days; Number of cycles: 6; Treatment dose: 19,700 mg; Prescribed dose: 425; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 471 days (1.3 years); Days to treatment end: 476 days (1.3 years); Treatment dose: 2,000 cGy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Fluorouracil; Treatment intent type: Palliative; Days to treatment start: 503 days (1.4 years); Number of cycles: 2; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
2. Metastasis of diagnosis 1 (Carcinoma, diffuse type), site: Liver. Age at diagnosis: 65.3 years (23,842 days); Days to diagnosis: 429 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 429 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 429 days (1.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 476 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 625 days (1.7 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D7-6519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-D7-6519-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-D7-6519-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 18.
- Sample TCGA-D7-6519-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D7-6519-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Cancer procurement city: Poznan; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-FU+ etoposidium.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-FU.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site other: cervix.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 625 days; disease-specific survival: no event (censored), 625 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 429 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D7-6519-01A-11D-1799-01): tumor purity 0.74, ploidy 3.28, whole-genome doublings 1.
